Somatic mutation profile of tumor specimen MP2PRT-PARVAC-TMP1-A (aliquot MP2PRT-PARVAC-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PARVAC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,138 days).
Specimen MP2PRT-PARVAC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1bf17df-f58b-45f7-a8db-b04607e0206c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVAC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVAC-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b06c16dd-de0e-4dcf-b2f5-9b22c39c7538

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Frame Shift Del 1, Nonsense Mutation 1, Silent 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR3B | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 23/393 reads (6%) | catalogued as rs1563161481; called by muse, mutect2
- AMOTL2 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749041511; called by muse, varscan2
- GLI2 | c.2209C>T p.R737W (on ENST00000361492 / NM_001374353.1; = p.R754W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138932004, COSV58036605; called by muse, mutect2
- LRRN1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1365997413, COSV60014930; called by muse, mutect2
- ALDH1L2 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.033); called by muse, mutect2
- QRSL1 | c.536_539del p.V179Gfs*9 | Frame Shift Del (DEL) | VAF 42/155 reads (27%) | called by pindel*, varscan2
- SLC6A2 | c.1448_1449insGGGT p.F483Lfs*95 | Frame Shift Ins (INS) | VAF 121/301 reads (40%) | called by mutect2, pindel, varscan2
- SRRM5 | c.1678T>C p.S560P | Missense Mutation (SNP) | VAF 35/762 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- TCF3 | c.1226_1237dup p.V409_A412dup | In Frame Ins (INS) | VAF 194/490 reads (40%) | called by mutect2, varscan2
- SLC6A15 | c.2193G>A p.*731= | Silent (SNP) | VAF 12/235 reads (5%) | called by muse, mutect2
